Surgical pathology report (de-identified scan), TCGA case TCGA-B9-5155, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-5155-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Diagnosis:

Kidney, right, nephrectomy

Histologic tumor type/subtype: Clear cell papillary renal cell carcinoma of end stage kidney (renal tumor #2 and a tiny tumor in specimen A13 away from the main tumor mass), papillary adenoma (renal tumor #1), and numerous tiny papillary adenomas.

Histologic grade (if applicable):

Tumor size (greatest dimension): The clear cell papillary renal cell carcinomas are 2.0 and 0.15 cm, the larger papillary adenoma is 2.0 cm, and the tiny papillary adenomas are 1-2 mm.

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: The larger clear cell papillary renal cell carcinoma focally extends into perirenal adipose tissue (block A6)

Gerota's fascia: not identified

Renal vein: not identified

Ureter: not identified

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: free of tumor

Gerota's fascia: free of tumor

Renal vein: free of tumor

Renal artery: free of tumor

Ureter: free of tumor

Adrenal gland: not present in specimen

Lymph nodes: none present in specimen

Other significant findings: The background kidney shows end stage renal disease, with numerous senescent glomeruli, atrophy of tubules, thinning of renal cortex, and arterionephrosclerosis.

AJCC Staging:

pT3

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with renal lesion.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right kidney".

Specimen fixation: Formalin

Type of specimen: Radical nephrectomy

[page 2 of 3]
Side of specimen: Right

Size and weight of specimen: Weight: 850 grams; Dimensions: 23.0 x 11.0 x 8.0 cm; Kidney dimensions: 11.0 x 8.0 x 7.0 cm. No adrenal gland is identified.

Orientation: The perinephric adipose tissue is inked green.

Presence/absence of adrenal gland: Not grossly identified

Tumor description/site: There is a tan/pink well-circumscribed nodule in the inferior pole which distorts the capsule. This nodule exhibits a central area of hemorrhage and necrosis. 1.5 cm superior to this nodule is a 0.4 cm in greatest dimension satellite lesion which is well-circumscribed tan/pink. Also present in the superior pole 6.5 cm parallel to the initial nodule is a well-circumscribed golden yellow/orange hemorrhagic soft nodule, which also distorts the capsule. Both of the nodules are present in the renal cortex.

Tumor size: The first tumor is 2.0 x 2.0 x 1.5 cm; the second nodule parallel to it is 2.0 x 1.5 x 1.5 cm.

Presence/absence of multicentricity: Present. One location is 2.5 cm superior to the first nodule, 0.3 cm in greatest dimension.

Confinement/non-confinement to the kidney: The nodules appear directly below the renal capsule, without definite extension through capsule.

Extent of invasion:

Perirenal adipose tissue: Tumor does not grossly involve

Gerota's fascia: Tumor grossly involves

Renal vein: Tumor does not grossly involve

Ureter: Tumor does not grossly involve

Other organs: Tumor does not grossly involve

Surgical margins:

Perirenal adipose tissue: Negative, appears to grossly abut

Renal vein: Negative. First nodule is 3.0 cm from the renal vein, second is 4.0 cm from renal vein margin.

Renal artery: Negative. First nodule is 3.5 cm from the renal artery, second is 5.0 cm from renal artery.

Ureter: Negative. First nodule is 3.7 cm from the ureter, second is 5.5 cm from the ureter.

Description of kidney away from tumor: The remainder of the kidney parenchyma is atrophic and diffusely cystic with a cortex and medulla that cannot be distinguished. There are multiple tiny white nodules in the renal cortex, ranging from 1-2 mm, away from the dominant tumor nodules.

Lymph nodes (hilar): A 2.3 cm in greatest dimension lymph node candidate is identified.

Other significant findings: The renal pelvis is markedly fatty.

Also received in the container is a detached portion of adipose tissue.

Tissue submitted for special investigations: Tumor and normal submitted to tissue procurement.

Digital photograph taken: No

Block Summary:

A1 - Ureter, vein and artery margins

A2 - First tumor with adjacent normal parenchyma

[page 3 of 3]
A3 - First tumor expanding the capsule
A4 - First tumor and closest ink
A5 - Second tumor with normal parenchyma
A6 - Second tumor with expanding capsule
A7 - Second tumor and closest ink
A8 - Normal kidney parenchyma
A9 - Representative section of cystic area in kidney
A10 - Hilar lymph node candidate and representative sections of the additional adipose tissue
A11-A14 - Additional sections of renal parenchyma, with tiny cortical white nodules sampled

Light Microscopy:

Light microscopic examination is performed

Source: NCI Genomic Data Commons file 8436604a-f294-48bb-90e4-e3caafcefc90 (TCGA-B9-5155.E00BD8FB-4B4E-4861-BE57-E5506B0B97A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).